Gene-level copy-number profile of tumor specimen TCGA-DX-A8BL-01A from TCGA case TCGA-DX-A8BL, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 59.5 years (21,728 days).
Specimen TCGA-DX-A8BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.cfeb9c17-ceb5-40b5-9459-dfc41a377a66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97014054-708a-4b5e-976a-6decb9bb1c04

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 823; copy number 2: 11,913; copy number 3: 20,934; copy number 4: 14,469; copy number 5: 4,025; copy number 6: 4,287; copy number 7: 2,048; copy number 8: 772; copy number 9: 323; copy number 10: 56; copy number 11: 63; copy number 12: 31; copy number 13: 39; copy number 15: 4; copy number 16: 2; copy number 27: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BL-01A-11D-A416-01): tumor purity 0.57, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,949 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,644,717, 375 genes, copy number 7 (broad region; genes not listed).
- chr3:85,992,183–87,793,629, 18 genes, copy number 7–27 (within-gene range 2–27): CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1.
- chr3:105,366,909–105,869,552, 2 genes, copy number 13: ALCAM, CBLB.
- chr3:116,645,902–116,850,367, 4 genes, copy number 15: BZW1P2, TUSC7, AC108713.1, MIR4447.
- chr3:191,267,168–191,398,659, 2 genes, copy number 16 (within-gene range 3–16): UTS2B, CCDC50.
- chr3:193,771,874–194,832,592, 37 genes, copy number 13 (within-gene range 3–13): AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1, CPN2, LRRC15, GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1, RNU6-1101P, RPL23AP93, TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2.
- chr4:123,539,026–123,962,698, 4 genes, copy number 8 (within-gene range 6–8): LINC01091, AC096732.1, RPL21P50, AC093767.1.
- chr6:6,901,022–7,881,728, 23 genes, copy number 8 (within-gene range 5–8): AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6.
- chr6:66,710,242–66,728,904, 2 genes, copy number 10: AL450336.1, RNU7-66P.
- chr8:80,594,815–92,879,502, 157 genes, copy number 7–11 (broad region; genes not listed).
- chr9:108,626,833–108,703,092, 2 genes, copy number 7: AL669983.1, AL358779.1.
- chr12:564,296–663,779, 1 gene, copy number 10 (within-gene range 3–10): NINJ2.
- chr12:589,530–991,190, 9 genes, copy number 10: RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr14:25,124,467–26,806,467, 12 genes, copy number 8: LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588.
- chr14:26,775,495–26,918,594, 5 genes, copy number 8: LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:28,264,390–37,596,059, 172 genes, copy number 7–10 (broad region; genes not listed).
- chr14:37,720,425–37,720,561, 1 gene, copy number 10: AL136296.1.
- chr15:23,685,400–24,912,924, 11 genes, copy number 8 (within-gene range 6–8): NDN, AC087490.1, RNU6-741P, PWRN4, PWRN1, PWRN2, AC087463.1, AC087463.2, AC087463.3, AC090983.2, NPAP1.
- chr15:60,479,152–60,630,637, 1 gene, copy number 8 (within-gene range 5–8): RORA-AS1.
- chr15:60,558,080–60,765,625, 8 genes, copy number 8: CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1.
- chr17:15,792,862–17,217,679, 65 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:17,972,813–22,706,703, 251 genes, copy number 7–8 (broad region; genes not listed).
- chr19:6,531,026–29,564,479, 985 genes, copy number 7–8 (broad region; genes not listed).
- chr19:29,811,991–31,466,431, 26 genes, copy number 9: CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1.
- chr19:38,770,971–46,677,447, 436 genes, copy number 8–12 (within-gene range 3–12) (broad region; genes not listed).
- chr20:30,403,123–32,439,319, 62 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:35,626,031–46,100,176, 278 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 814. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
